Somatic mutation profile of tumor specimen TARGET-20-PASFEW-04A (aliquot TARGET-20-PASFEW-04A-01D) from TARGET case TARGET-20-PASFEW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (428 days).
Specimen TARGET-20-PASFEW-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f517dc6-b810-418b-ae64-efc6d7e10c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFEW-14A (Bone Marrow Normal), aliquot TARGET-20-PASFEW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2b6c557-591f-4485-8eb9-7818eeca7da7

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TCP11 | c.994G>A p.V332I (on ENST00000512012; = p.V270I on NM_018679.5) | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765786893, COSV55131752, COSV55133326; called by muse, mutect2, varscan2
- CASR | c.2933T>C p.V978A (on ENST00000490131; = p.V1055A on NM_000388.4) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
